Somatic mutation profile of tumor specimen ALCH-B1J2-TTP1-A (aliquot ALCH-B1J2-TTP1-A-1-0-D-A714-36) from ALCHEMIST case ALCH-B1J2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 80.5 years (29,397 days).
Specimen ALCH-B1J2-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70bb77d1-0567-4373-a9d1-ca9dd1fb1433.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1J2-NB1-A (Blood Derived Normal), aliquot ALCH-B1J2-NB1-A-1-0-D-A714-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4810b60e-e6e1-42f5-97b2-ce0565ef15c4

The open-access MAF lists 139 somatic variants for this specimen: 95 protein-altering or splice-affecting, 25 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 25, Intron 8, Nonsense Mutation 7, 5'UTR 4, Frame Shift Del 4, 3'Flank 2, Splice Site 2, 5'Flank 2, RNA 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 95/486 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 45/193 reads (23%) | hotspot (GDC flag); catalogued as rs764735889, COSV52685086, COSV53209009; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AGER | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 63/273 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.873); catalogued as rs766294601; called by muse, mutect2, varscan2
- CALCR | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 22/313 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs368981699, COSV100810718; called by muse, mutect2
- CCDC39 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 57/446 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as rs1470125398, COSV56483008; called by muse, mutect2, varscan2
- CD109 | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 52/336 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs758558743, COSV54645869; called by muse, varscan2
- CEP164 | c.3172G>C p.E1058Q | Missense Mutation (SNP) | VAF 36/272 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as rs748972612; called by muse, mutect2, varscan2
- CHM | c.1917C>G p.F639L | Missense Mutation (SNP) | VAF 95/510 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100753556; called by muse, mutect2, varscan2
- COPS5 | c.451G>C p.D151H | Missense Mutation (SNP) | VAF 32/313 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63474426; called by muse, mutect2, varscan2
- CR2 | c.2915C>T p.S972L | Missense Mutation (SNP) | VAF 36/505 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.116); catalogued as rs772806588; called by muse, mutect2
- CRB2 | c.3274G>A p.E1092K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as rs542637649; called by muse, mutect2, varscan2
- CTSW | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 30/252 reads (12%) | catalogued as COSV57173455; called by muse, mutect2, varscan2
- DCLRE1A | c.2945G>A p.G982E | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs749184512; called by muse, mutect2, varscan2
- DNAJC4 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.857); catalogued as rs761896083; called by muse, varscan2
- DYNC1LI2 | c.188A>G p.D63G | Missense Mutation (SNP) | VAF 31/250 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs766782099; called by muse, mutect2, varscan2
- GANAB | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 25/275 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV100647856; called by muse, mutect2
- GNAL | c.284C>T p.S95L (on ENST00000269162 / NM_001142339.3; = p.S172L on NM_182978.4) | Missense Mutation (SNP) | VAF 41/289 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as CM135987; called by muse, mutect2, varscan2
- LHX8 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 54/483 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.59); catalogued as rs756269952; called by muse, mutect2, varscan2
- MECP2 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as COSV57652741; called by muse, mutect2, varscan2
- MEGF8 | c.4223G>T p.G1408V (on ENST00000251268 / NM_001271938.2; = p.G1341V on NM_001410.3) | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.974); catalogued as COSV52101122; called by muse, mutect2
- MSANTD1 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1021225291, COSV101433691; called by muse, mutect2, varscan2
- MTHFD2 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs749729793; called by muse, mutect2, varscan2
- OR14A2 | c.751A>G p.I251V | Missense Mutation (SNP) | VAF 77/417 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1229325925; called by muse, varscan2
- OR1L1 | c.809G>C p.R270T (on ENST00000373686; = p.R220T on NM_001005236.3) | Missense Mutation (SNP) | VAF 41/285 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.854); catalogued as COSV100542176, COSV58935647; called by muse, mutect2, varscan2
- OR52E8 | c.261G>T p.M87I | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs749825378; called by muse, mutect2
- PACRGL | c.544C>G p.L182V | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.721); catalogued as rs750811099; called by muse, mutect2, varscan2
- POM121L12 | c.274G>T p.V92L | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs765486759; called by muse, mutect2, varscan2
- RAVER2 | c.1176G>C p.L392F | Missense Mutation (SNP) | VAF 38/412 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV53807522, COSV53811492; called by muse, mutect2
- SLC9A6 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 25/271 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.069); catalogued as rs1556614799; called by muse, mutect2
- UNC13B | c.4066G>A p.D1356N | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV101036403; called by muse, mutect2, varscan2
- ZNF223 | c.493C>A p.L165I | Missense Mutation (SNP) | VAF 51/482 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.437); catalogued as rs1041106235; called by muse, mutect2, varscan2
- ABCA7 | c.4129del p.E1377Kfs*6 | Frame Shift Del (DEL) | VAF 16/95 reads (17%) | called by mutect2, pindel, varscan2
- ADAMTS13 | c.1686C>G p.F562L | Missense Mutation (SNP) | VAF 29/243 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- ADGRG2 | c.1735+1G>C p.X579_splice (on ENST00000379869 / NM_001079858.3; = p.X576_splice on NM_005756.4) | Splice Site (SNP) | VAF 38/339 reads (11%) | called by muse, mutect2, varscan2
- AEBP1 | c.1814C>G p.S605* | Nonsense Mutation (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- AHNAK | c.15838C>G p.L5280V | Missense Mutation (SNP) | VAF 45/246 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ALKBH8 | c.502C>T p.Q168* | Nonsense Mutation (SNP) | VAF 39/242 reads (16%) | called by muse, mutect2, varscan2
- ARFGAP1 | c.588dup p.D197Rfs*2 | Frame Shift Ins (INS) | VAF 19/189 reads (10%) | called by mutect2, pindel
- ARSF | c.1174C>A p.P392T | Missense Mutation (SNP) | VAF 42/464 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); called by muse, mutect2
- BDP1 | c.1263G>C p.M421I | Missense Mutation (SNP) | VAF 42/264 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, varscan2
- BTF3L4 | c.185A>T p.D62V | Missense Mutation (SNP) | VAF 16/225 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2
- CCDC88A | c.2380C>G p.Q794E | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- CD72 | c.65C>A p.S22Y | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CDKL3 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 51/492 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CHADL | c.2102G>A p.C701Y | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCAF12L2 | c.547G>C p.D183H | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- DOCK8 | c.825G>C p.L275F | Missense Mutation (SNP) | VAF 78/776 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ENPP1 | c.1117G>C p.E373Q | Missense Mutation (SNP) | VAF 74/578 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPHB2 | c.2440A>T p.I814F (on ENST00000400191 / NM_001309193.2; = p.I815F on NM_004442.7) | Missense Mutation (SNP) | VAF 50/263 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FBXO10 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIN2D | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- GUCY2C | c.262C>G p.L88V | Missense Mutation (SNP) | VAF 44/311 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HNRNPM | c.811G>C p.D271H | Missense Mutation (SNP) | VAF 48/477 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2
- HOOK1 | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 40/372 reads (11%) | called by muse, mutect2
- HSPA14 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 29/270 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- ITGA2B | c.1947G>A p.V649= | Splice Region (SNP) | VAF 17/125 reads (14%) | called by muse, mutect2, varscan2
- ITGB6 | c.29_32del p.F10Yfs*3 | Frame Shift Del (DEL) | VAF 35/348 reads (10%) | called by pindel, varscan2
- KPNB1 | c.920del p.P307Lfs*24 | Frame Shift Del (DEL) | VAF 49/344 reads (14%) | called by mutect2, pindel, varscan2
- KYNU | c.625G>C p.E209Q | Missense Mutation (SNP) | VAF 34/436 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2
- LAMB3 | c.651G>C p.L217F | Missense Mutation (SNP) | VAF 62/386 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- LDHB | c.814C>T p.H272Y | Missense Mutation (SNP) | VAF 87/574 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- LRP1B | c.13545G>A p.M4515I | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP1B | c.3388G>A p.D1130N | Missense Mutation (SNP) | VAF 44/318 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAPK8IP3 | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- NDFIP1 | c.523G>C p.D175H | Missense Mutation (SNP) | VAF 64/501 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- NEMF | c.1295A>G p.K432R | Missense Mutation (SNP) | VAF 64/312 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- NPHS1 | c.3499G>A p.E1167K | Missense Mutation (SNP) | VAF 67/485 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- OR14A2 | c.880G>C p.D294H | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, varscan2
- P2RX6 | c.909G>A p.W303* | Nonsense Mutation (SNP) | VAF 27/157 reads (17%) | called by muse, mutect2, varscan2
- PEAK1 | c.3028G>C p.D1010H | Missense Mutation (SNP) | VAF 24/374 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.131); called by muse, mutect2
- PIEZO2 | c.854G>C p.G285A | Missense Mutation (SNP) | VAF 48/427 reads (11%) | SIFT tolerated (1); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- PIK3R6 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by mutect2, varscan2
- PLXNB2 | c.4860C>G p.I1620M | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- POU3F4 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- PPP2R2C | c.31C>G p.Q11E | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKDC | c.12144G>C p.K4048N | Missense Mutation (SNP) | VAF 73/468 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.141); called by muse, varscan2
- RASGRF1 | c.3240G>A p.M1080I | Missense Mutation (SNP) | VAF 49/346 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ROM1 | c.589G>C p.D197H | Missense Mutation (SNP) | VAF 40/285 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- RSC1A1 | c.1355G>C p.G452A | Missense Mutation (SNP) | VAF 27/478 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.254); called by muse, mutect2
- RTL1 | c.2050G>C p.D684H | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- RWDD3 | c.17A>T p.Q6L | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC9A9 | c.1470-1G>A p.X490_splice | Splice Site (SNP) | VAF 75/631 reads (12%) | called by muse, mutect2, varscan2
- SMC3 | c.1853G>C p.R618T | Missense Mutation (SNP) | VAF 74/473 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- SSTR5 | c.506G>T p.C169F | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2
- STAG2 | c.1589G>T p.R530I | Missense Mutation (SNP) | VAF 47/466 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2
- SUOX | c.1521_1524del p.C508Rfs*109 | Frame Shift Del (DEL) | VAF 61/357 reads (17%) | called by pindel, varscan2
- TEX48 | c.329G>T p.W110L | Missense Mutation (SNP) | VAF 42/306 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- THADA | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 55/493 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- TJP1 | c.4553A>T p.K1518I | Missense Mutation (SNP) | VAF 39/243 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- TMEFF1 | c.1055C>T p.T352I | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRPS1 | c.121C>T p.Q41* (on ENST00000220888 / NM_001330599.2; = p.Q54* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 72/622 reads (12%) | called by muse, mutect2, varscan2
- TUBE1 | c.883C>G p.Q295E | Missense Mutation (SNP) | VAF 33/292 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ZFP69 | c.139C>G p.Q47E | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF12 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- ZNF608 | c.1340C>T p.S447F | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ADAM11 | c.663G>A p.L221= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as rs1254353387, COSV52345676; called by muse, varscan2
- AL353579.1 | c.486C>G p.L162= | Silent (SNP) | VAF 11/67 reads (16%) | called by muse, mutect2, varscan2
- CLCA1 | c.2277G>A p.L759= | Silent (SNP) | VAF 18/248 reads (7%) | called by muse, mutect2
- CPA6 | c.510G>A p.E170= | Silent (SNP) | VAF 42/258 reads (16%) | called by muse, mutect2
- DHX38 | c.2922C>T p.I974= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as rs770097854, COSV51700869; called by muse, mutect2, varscan2
- DNAI1 | c.675C>T p.A225= | Silent (SNP) | VAF 66/582 reads (11%) | catalogued as COSV99646886; called by muse, mutect2, varscan2
- FCMR | c.510C>A p.G170= | Silent (SNP) | VAF 72/307 reads (23%) | called by muse, mutect2, varscan2
- FMNL2 | c.1758C>T p.P586= | Silent (SNP) | VAF 51/388 reads (13%) | catalogued as rs771444096, COSV99980360; called by muse, mutect2, varscan2
- HS6ST2 | c.1617G>A p.Q539= | Silent (SNP) | VAF 29/162 reads (18%) | called by muse, mutect2, varscan2
- MAPK8IP3 | c.567A>T p.G189= | Silent (SNP) | VAF 19/145 reads (13%) | called by muse, mutect2, varscan2
- MTMR1 | c.1182G>A p.S394= | Silent (SNP) | VAF 33/194 reads (17%) | catalogued as rs781823123; called by muse, mutect2, varscan2
- MYH7 | c.5007G>A p.E1669= | Silent (SNP) | VAF 26/440 reads (6%) | catalogued as CD146977; called by muse, mutect2
- NLRP12 | c.417C>T p.L139= | Silent (SNP) | VAF 44/376 reads (12%) | catalogued as rs759376100; called by muse, mutect2, varscan2
- PHAX | c.870G>A p.L290= | Silent (SNP) | VAF 18/300 reads (6%) | catalogued as rs767933132; called by muse, mutect2
- PLXNA4 | c.2349C>A p.V783= | Silent (SNP) | VAF 28/286 reads (10%) | catalogued as COSV100324397; called by muse, mutect2
- PPP4R3C | c.456C>T p.F152= | Silent (SNP) | VAF 36/336 reads (11%) | called by muse, mutect2, varscan2
- PPP6R2 | c.510C>T p.V170= | Silent (SNP) | VAF 22/171 reads (13%) | catalogued as rs1400805793; called by muse, mutect2, varscan2
- SFTPC | c.303C>T p.L101= | Silent (SNP) | VAF 18/266 reads (7%) | catalogued as rs370825102; called by muse, mutect2
- SHB | c.171G>C p.P57= | Silent (SNP) | VAF 14/81 reads (17%) | called by muse, mutect2, varscan2
- SLC27A1 | c.153G>C p.A51= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as COSV53095587; called by muse, mutect2
- SMOC1 | c.696G>A p.Q232= | Silent (SNP) | VAF 22/283 reads (8%) | called by muse, mutect2
- TAF1C | c.1764C>G p.L588= | Silent (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2
- TGM7 | c.1698C>T p.L566= | Silent (SNP) | VAF 9/113 reads (8%) | called by muse, mutect2
- ZFYVE1 | c.2229C>T p.G743= | Silent (SNP) | VAF 13/342 reads (4%) | called by muse, mutect2
- ZFYVE26 | c.2961C>G p.T987= | Silent (SNP) | VAF 24/418 reads (6%) | called by muse, mutect2
- AC134312.1 | n.349G>T | RNA (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504135 G>C | 5'Flank (SNP) | VAF 29/196 reads (15%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504136 C>T | 5'Flank (SNP) | VAF 29/195 reads (15%) | called by muse, mutect2, varscan2
- BBS4 | c.24+165C>T | Intron (SNP) | VAF 26/424 reads (6%) | called by muse, mutect2
- CRB2 | c.3389+61G>A | Intron (SNP) | VAF 20/125 reads (16%) | called by muse, mutect2, varscan2
- CYP17A1 | c.753+16G>A | Intron (SNP) | VAF 47/299 reads (16%) | called by muse, mutect2, varscan2
- FAM86C2P | n.1045C>T | RNA (SNP) | VAF 25/323 reads (8%) | catalogued as rs567454542; called by muse, mutect2
- FBLN7 | c.-70C>T | 5'UTR (SNP) | VAF 9/83 reads (11%) | called by muse, mutect2
- FHL1 | c.-26-9564G>A | Intron (SNP) | VAF 41/337 reads (12%) | called by muse, mutect2, varscan2
- GUSBP3 | chr5:69635378 C>G | 3'Flank (SNP) | VAF 21/287 reads (7%) | called by muse, mutect2, varscan2
- HELZ | c.247+27A>C | Intron (SNP) | VAF 55/478 reads (12%) | called by muse, mutect2, varscan2
- JADE3 | c.-5C>G | 5'UTR (SNP) | VAF 25/386 reads (6%) | catalogued as COSV99510317; called by muse, mutect2
- NHLRC1 | c.-28G>A | 5'UTR (SNP) | VAF 17/72 reads (24%) | catalogued as rs1194228782, COSV61481973; called by muse, mutect2, varscan2
- PDIA3P1 | chr1:147179290 G>A | 3'Flank (SNP) | VAF 52/736 reads (7%) | called by muse, mutect2
- PPFIA2 | c.1131+25C>G | Intron (SNP) | VAF 78/398 reads (20%) | called by muse, mutect2, varscan2
- RGL4 | c.*149C>A | 3'UTR (SNP) | VAF 36/332 reads (11%) | called by muse, mutect2, varscan2
- RHOT1 | c.-13G>T | 5'UTR (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- SPACA3 | c.34+992G>C | Intron (SNP) | VAF 48/281 reads (17%) | called by muse, mutect2, varscan2
- SUB1 | c.195+2944G>A | Intron (SNP) | VAF 30/476 reads (6%) | called by muse, mutect2
